Somatic mutation profile of tumor specimen 436db08d-c316-44b5-b0de-62617d (aliquot 436db08d-c316-44b5-b0de-62617d_D6_1) from CPTAC case 11BR010, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 35.5 years (12,957 days).
Specimen 436db08d-c316-44b5-b0de-62617d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dddddcfa-0eb1-44ce-ab02-0ac4ea8d2038.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen b6c9faff-5782-45d1-895c-3e9cf5 (Blood Derived Normal), aliquot b6c9faff-5782-45d1-895c-3e9cf5_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55946b20-60f5-4385-8e17-e26c4e4d3280

The open-access MAF lists 67 somatic variants for this specimen: 39 protein-altering or splice-affecting, 21 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 21, Nonsense Mutation 5, Intron 5, 5'Flank 2, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 26/99 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.981T>G p.Y327* | Nonsense Mutation (SNP) | VAF 58/211 reads (27%) | catalogued as rs879254077, COSV52678878, COSV52914365, COSV52993701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTDSPL2 | c.164T>A p.F55Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as COSV52945681; called by muse, varscan2
- EPYC | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs745867926, COSV53798426, COSV53800078; called by muse, mutect2, varscan2
- FOXRED2 | c.1625-1G>A p.X542_splice | Splice Site (SNP) | VAF 25/93 reads (27%) | catalogued as COSV53400646; called by muse, mutect2, varscan2
- GLB1L2 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 16/158 reads (10%) | catalogued as rs1234806934; called by muse, mutect2, varscan2
- HOXA5 | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56073860; called by muse, varscan2
- NLRP14 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV55065050; called by muse, mutect2, varscan2
- NOXA1 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs748396276; called by muse, mutect2
- PDE1A | c.924G>C p.L308F | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as rs977354279, COSV59515168; called by muse, mutect2, varscan2
- PHKB | c.3134T>C p.I1045T | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs200896827; called by muse, mutect2, varscan2
- PYCR3 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1168469742, COSV55306286, COSV55306469, COSV55308125; called by muse, mutect2, varscan2
- QDPR | c.73C>G p.R25G | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV55552366; called by muse, mutect2, varscan2
- ROR1 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs776096406; called by muse, mutect2
- RYR2 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.974); catalogued as COSV63694226; called by muse, mutect2, varscan2
- SLC22A11 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 221/446 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs963041074, COSV57251864; called by muse, mutect2, varscan2
- TMPRSS15 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV53042867; called by muse, mutect2, varscan2
- TRAPPC9 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 118/373 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.747); catalogued as COSV66892455; called by muse, mutect2, varscan2
- WRAP73 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs143970017; called by muse, mutect2, varscan2
- ANPEP | c.1427C>G p.S476C | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ARHGAP26 | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2
- ARHGAP35 | c.2483T>C p.L828P | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN2 | c.3805C>T p.R1269* (on ENST00000313400 / NM_001365069.1; = p.R1218* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 25/181 reads (14%) | called by muse, mutect2, varscan2
- CALD1 | c.1639G>T p.E547* (on ENST00000361675 / NM_033138.4; = p.E292* on NM_004342.7) | Nonsense Mutation (SNP) | VAF 36/424 reads (8%) | called by muse, mutect2
- DDI2 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- DKKL1 | c.625C>A p.H209N | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DNAH5 | c.2449C>G p.L817V | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM171A1 | c.1714A>C p.S572R | Missense Mutation (SNP) | VAF 44/700 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2
- HAUS8 | c.1203_1205del p.L402del | In Frame Del (DEL) | VAF 18/101 reads (18%) | called by mutect2, pindel, varscan2
- MUC22 | c.468C>A p.S156R | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated, low confidence (0.28); called by muse, mutect2, varscan2
- PPM1H | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAPGEF1 | c.2986C>G p.H996D | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- RNF43 | c.1337C>A p.S446Y | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SERPINB12 | c.1064A>G p.N355S | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2
- SMAD3 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 114/478 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SPINK7 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.142); called by muse, mutect2
- SUV39H1 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.027); called by muse, mutect2
- TNIK | c.4008dup p.A1337Cfs*9 | Frame Shift Ins (INS) | VAF 26/146 reads (18%) | called by mutect2, pindel, varscan2
- ZNF550 | c.429G>C p.E143D | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALAD | c.60G>A p.Q20= | Silent (SNP) | VAF 23/156 reads (15%) | called by muse, mutect2, varscan2
- APBA1 | c.552C>T p.S184= | Silent (SNP) | VAF 33/239 reads (14%) | catalogued as COSV55230995; called by muse, mutect2, varscan2
- CATSPER1 | c.1377C>T p.L459= | Silent (SNP) | VAF 30/416 reads (7%) | called by muse, mutect2
- CRAT | c.1722C>T p.Y574= | Silent (SNP) | VAF 39/316 reads (12%) | catalogued as rs746038243, COSV100540031; called by muse, mutect2, varscan2
- CYP7B1 | c.714C>G p.V238= | Silent (SNP) | VAF 75/364 reads (21%) | called by muse, mutect2, varscan2
- EIF3M | c.628C>A p.R210= | Silent (SNP) | VAF 5/101 reads (5%) | called by muse, mutect2
- EYS | c.519C>T p.F173= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV60999913; called by muse, mutect2, varscan2
- FMO3 | c.813G>A p.L271= | Silent (SNP) | VAF 45/394 reads (11%) | called by muse, mutect2, varscan2
- GRAP | c.369G>A p.E123= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as COSV99408202; called by muse, mutect2
- KRT33B | c.144C>T p.C48= | Silent (SNP) | VAF 165/528 reads (31%) | catalogued as rs183730836; called by muse, mutect2, varscan2
- MYLK | c.3009G>T p.L1003= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV60624786; called by muse, mutect2
- PUM3 | c.1875G>A p.L625= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- RBMXL2 | c.564C>T p.D188= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1395537265; called by muse, mutect2
- SCN10A | c.2679C>T p.F893= | Silent (SNP) | VAF 48/165 reads (29%) | called by muse, mutect2, varscan2
- STX11 | c.462C>T p.R154= | Silent (SNP) | VAF 81/666 reads (12%) | catalogued as COSV62448895; called by muse, mutect2, varscan2
- SYNGAP1 | c.3313C>A p.R1105= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- TAF1A | c.768C>G p.A256= | Silent (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2, varscan2
- THRB | c.120G>A p.K40= | Silent (SNP) | VAF 14/264 reads (5%) | catalogued as rs1441673077; called by muse, mutect2
- TNFRSF9 | c.585G>A p.T195= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs151279644; called by muse, mutect2, varscan2
- TRIM66 | c.219C>G p.L73= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as rs1342651182; called by muse, mutect2, varscan2
- TTN | c.72702T>C p.V24234= (on ENST00000591111; = p.V16810= on NM_003319.4) | Silent (SNP) | VAF 65/224 reads (29%) | called by muse, mutect2, varscan2
- ANKRD33 | c.664+37C>T | Intron (SNP) | VAF 66/297 reads (22%) | catalogued as rs138166001; called by muse, mutect2, varscan2
- ASH1L | chr1:155563225 C>T | 5'Flank (SNP) | VAF 17/156 reads (11%) | catalogued as rs1235387657; called by muse, mutect2, varscan2
- CXCR5 | c.51+2454C>T | Intron (SNP) | VAF 6/25 reads (24%) | catalogued as rs1252524423; called by muse, mutect2, varscan2
- FRMD4A | c.1117+182C>T | Intron (SNP) | VAF 97/371 reads (26%) | called by muse, mutect2, varscan2
- IMPDH2 | chr3:49029500 C>G | 5'Flank (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- TCEA2 | c.517+164G>A | Intron (SNP) | VAF 47/174 reads (27%) | called by muse, mutect2, varscan2
- ZNF177 | c.33+14T>A | Intron (SNP) | VAF 27/95 reads (28%) | called by muse, mutect2, varscan2
